Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70E, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70E-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology (	Final Results
Surgical Pathology	Final

CASE NUMBER:

DIAGNOSIS: Adrenal gland, right, adrenalectomy: Pheochromocytoma. No capsular or vascular invasion identified (see note).

NOTE: Tumor cells stain positively for chromogranin and synaptophysin and S-100 immunostain highlights sustentacular cells. These findings support the diagnosis of pheochromocytoma.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology, . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol:

Brief Clinical History: pheo.

Specimen Taken For Protocol: 01 - Yes.

PROCEDURE:

Pre-Operative Diagnosis: pheo.

Post-Operative Diagnosis: pheo.

Operative Findings: same.

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received fresh is a specimen labeled with the patient's name, medical record number, and further specified "Right Adrenal Gland", consisting of an adrenalectomy specimen weighing 21 grams and measuring 5.5 x 2.5 x 2.0 cm with associated fat measuring 3.5 x 2.5 x 1.3 cm. There is an associated ovoid nodule measuring 2.5 x 2.0 x 2.0 cm. The nodule is inked in black and bisected to reveal a fleshy maroon-tan cut surface. Gross photographs are taken. Approximately 50% of the tissue from the center of the nodule is procured for and a fragment of adipose tissue measuring 1.0 x 1.0 x 1.0 cm is procured for . The remained of the specimen is placed into formalin and submitted to pathology for permanent processing. The procurement was performed and documented by . Received in is a specimen matching the above description. Representative sections of the tumor and associated normal adrenal gland tissue are submitted for permanent processing and the remainder of the tissue is returned to formalin. Summary of cassettes is as follows:

Cassettes representative sections of tumor adjacent to normal adrenal gland
Cassette normal adrenal gland

[page 2 of 2]
Surgical Pathology

Final Results

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file e2d5e42e-fe7c-4ee0-add2-6820303c5ef2 (TCGA-QR-A70E.089504D5-ED7E-43B6-BD5B-0FFBA9171AF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).